Gene-level copy-number profile of tumor specimen TARGET-40-0A4I5B-01A from TARGET case TARGET-40-0A4I5B, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 20.8 years (7,615 days).
Specimen TARGET-40-0A4I5B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.c00798e9-eb10-5832-825e-b73ab02282b4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I5B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 404 have no estimate.
https://portal.gdc.cancer.gov/files/5f0d419d-cab1-4a8e-b96e-f894fd0649ad

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1,623; copy number 1: 1,201; copy number 2: 6,720; copy number 3: 18,122; copy number 4: 15,975; copy number 5: 9,436; copy number 6: 5,664; copy number 7: 1,118; copy number 8: 150; copy number 9: 47; copy number 10: 37; copy number 11: 116; copy number 14: 9; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,478 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,861,054–42,424,232, 31 genes, copy number 7: CITED4, AC119677.1, AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1, SCMH1, RPL23AP17, AC093151.7, AC093151.2, AC093151.1, AC093151.5, FOXO6, FOXO6-AS1, RNA5SP45, EDN2, HIVEP3, AL445933.2, AL445933.1, AC119676.1, AL158216.1, HNRNPFP1, AC114492.1, GUCA2B, GUCA2A, FOXJ3, AC096540.1, RIMKLA, AL513331.1.
- chr2:142,131,178–154,457,438, 139 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr4:68,509,441–68,628,899, 5 genes, copy number 14: UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3.
- chr6:6,169,304–6,169,435, 2 genes, copy number 8: MIR7853, MIR5683.
- chr8:81,656,914–108,083,642, 430 genes, copy number 7–14 (within-gene range 6–14) (broad region; genes not listed).
- chr9:133,663,560–133,739,955, 1 gene, copy number 7 (within-gene range 4–7): SARDH.
- chr10:46,233,885–48,060,016, 54 genes, copy number 8: ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R, GPRIN2, SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P, FAM245B, CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P, FRMPD2B, PTPN20, GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7.
- chr11:101,890,674–102,530,750, 19 genes, copy number 7: ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7.
- chr11:102,681,310–104,682,581, 35 genes, copy number 8: AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552, AP001485.1.
- chr14:22,630,929–22,644,352, 1 gene, copy number 15 (within-gene range 6–15): OR6J1.
- chr14:105,785,505–106,461,055, 116 genes, copy number 11 (broad region; genes not listed).
- chr15:71,792,638–73,368,958, 47 genes, copy number 7–10: NR2E3, AC104938.1, MYO9A, RNA5SP399, AC022872.1, EIF5A2P1, RNU2-65P, SENP8, AC020779.1, AC020779.2, GRAMD2A, PKM, PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, AC103874.1, NPM1P42, NEO1, FKBP1AP2, NPM1P43, AC068397.1, HCN4, AC068397.2.
- chr15:74,299,503–76,059,795, 94 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr15:83,654,088–84,039,842, 1 gene, copy number 7 (within-gene range 6–7): ADAMTSL3.
- chr15:83,962,176–101,933,350, 436 genes, copy number 7 (broad region; genes not listed).
- chr17:46,193,576–46,361,797, 8 genes, copy number 7 (within-gene range 3–7): KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P.
- chr17:80,101,556–80,119,881, 1 gene, copy number 10: GAA.
- chr19:27,638,483–28,396,428, 18 genes, copy number 8: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1.
- chr22:19,121,529–20,016,823, 40 genes, copy number 7: AC004471.1, AC004471.2, TSSK1A, ESS2, TSSK2, GSC2, LINC01311, SLC25A1, CLTCL1, AC000072.1, AC000081.1, AC000081.2, KRT18P62, AC000085.1, HIRA, C22orf39, RN7SL168P, MRPL40, AC000068.1, UFD1, AC000068.3, AC000068.2, CDC45, AC000082.1, CLDN5, LINC00895, AC000077.1, AC000067.1, SEPTIN5, AC000093.1, GP1BB, TBX1, GNB1L, AC000089.1, RTL10, TXNRD2, AC000078.1, COMT, MIR4761, ARVCF.

Autosomal genes at a single copy (total copy number 1): 726. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
